Somatic mutation profile of tumor specimen TCGA-FV-A495-01A (aliquot TCGA-FV-A495-01A-11D-A25V-10) from TCGA case TCGA-FV-A495, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 51.3 years (18,740 days).
Specimen TCGA-FV-A495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22079af2-9809-4652-9f05-95e979e4673f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A495-10A (Blood Derived Normal), aliquot TCGA-FV-A495-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50368772-51af-4559-a0fb-4a548f155543

The open-access MAF lists 118 somatic variants for this specimen: 85 protein-altering or splice-affecting, 22 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 22, Nonsense Mutation 7, Intron 6, In Frame Del 3, Frame Shift Del 3, 3'UTR 3, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB2 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60006098; called by muse, mutect2, varscan2
- AMOT | c.3089G>C p.S1030T (on ENST00000371959 / NM_001113490.1; = p.S621T on NM_133265.3) | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV59067162, COSV59068183; called by muse, mutect2, varscan2
- ARFGEF3 | c.4595C>T p.A1532V | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52467805; called by muse, mutect2, varscan2
- ARHGEF3 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV56331202; called by mutect2, varscan2
- ARMCX5-GPRASP2 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs766817967, COSV63438816; called by muse, mutect2, varscan2
- ATP8A1 | c.1562T>C p.V521A | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as COSV52545430; called by muse, mutect2, varscan2
- BRIX1 | c.757T>G p.L253V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV57762168; called by muse, mutect2, varscan2
- CAPZB | c.15G>C p.Q5H | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51650941; called by muse, mutect2
- CEP85L | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs138089888; called by muse, mutect2, varscan2
- CFAP47 | c.7910A>T p.K2637M | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV66220030; called by muse, mutect2
- CHD2 | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67713465; called by muse, mutect2, varscan2
- CHIC1 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as COSV65157002; called by muse, mutect2
- CLASP1 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV55335990; called by muse, mutect2, varscan2
- CUX1 | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52911233; called by muse, mutect2
- CXorf58 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64858726; called by muse, mutect2, varscan2
- DCHS1 | c.2104A>G p.T702A | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55041056; called by muse, mutect2, varscan2
- DMD | c.10753C>T p.Q3585* | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | catalogued as COSV58941990; called by muse, mutect2
- DOK3 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751359031, COSV57254061; called by muse, mutect2, varscan2
- EVC2 | c.1601G>A p.R534K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60391013, COSV60400501; called by muse, mutect2, varscan2
- FADD | c.26A>G p.H9R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV57229701; called by muse, varscan2
- FHAD1 | c.2388G>C p.E796D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV58989537; called by muse, mutect2, varscan2
- FLNA | c.4581T>A p.D1527E | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV61049237; called by muse, mutect2, varscan2
- GAS2L3 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV57158742; called by muse, mutect2, varscan2
- GIN1 | c.722G>A p.S241N | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV67537606; called by muse, mutect2
- GOLT1B | c.333A>T p.R111S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV57554047; called by muse, mutect2, varscan2
- GPR173 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60237700; called by muse, mutect2, varscan2
- GPR174 | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 115/461 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52132540, COSV52133832; called by muse, mutect2, varscan2
- GPR82 | c.700T>A p.C234S | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV56888050; called by muse, varscan2
- GRAMD2A | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV59034903; called by muse, mutect2, varscan2
- HAGHL | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52403955; called by muse, mutect2, varscan2
- KCNK16 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV64678975; called by muse, mutect2, varscan2
- KRT79 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as COSV57939149, COSV57939909; called by muse, mutect2
- LEPR | c.3311T>A p.F1104Y | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV62750897; called by muse, mutect2
- LILRB1 | c.721C>T p.P241S (on ENST00000427581; = p.P205S on NM_006669.6) | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV61116765, COSV61118652; called by muse, varscan2
- MAGEL2 | c.3138G>T p.M1046I | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV58568669; called by muse, mutect2, varscan2
- MICA | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.028); catalogued as COSV69826958; called by muse, mutect2, varscan2
- MUC5B | c.8708C>T p.A2903V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs535181655; called by mutect2, varscan2
- MYH15 | c.3640G>C p.E1214Q | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56304697; called by muse, mutect2
- MYOF | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as rs199504349, COSV63706702; called by muse, mutect2, varscan2
- OVOL2 | c.786C>G p.H262Q | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV53861742; called by muse, mutect2
- PCDH15 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.349); catalogued as rs929285864, COSV57374623; called by muse, mutect2, varscan2
- PCDHA5 | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV65356302; called by muse, mutect2, varscan2
- PCDHAC1 | c.1363G>C p.A455P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV53864931; called by muse, mutect2, varscan2
- PEG3 | c.2111A>T p.Q704L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV55644045; called by muse, mutect2, varscan2
- PFKFB1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 47/151 reads (31%) | PolyPhen probably damaging (0.954); catalogued as COSV66629150; called by muse, mutect2, varscan2
- PKHD1L1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV65748065, COSV65750348; called by muse, mutect2, varscan2
- PKHD1L1 | c.12661G>T p.G4221* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | catalogued as COSV65742704, COSV65750353; called by muse, mutect2, varscan2
- PLCE1 | c.6683C>A p.A2228E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV53366808; called by muse, mutect2, varscan2
- PPP5C | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50142725; called by muse, mutect2, varscan2
- PRDM9 | c.1997G>A p.C666Y | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57011538; called by muse, varscan2
- RGSL1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 11/351 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs896098429, COSV54257292; called by muse, mutect2
- SBNO1 | c.3914A>T p.Y1305F (on ENST00000420886; = p.Y1304F on NM_018183.5) | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV57344872; called by muse, mutect2, varscan2
- SCN5A | c.1751G>A p.G584D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.112); catalogued as COSV61137643; called by muse, mutect2, varscan2
- SLC27A6 | c.1628A>G p.E543G | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV52486626; called by muse, mutect2
- SLC7A13 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV52536524; called by muse, mutect2, varscan2
- SPECC1 | c.1720A>G p.T574A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54964306; called by muse, mutect2, varscan2
- SPHKAP | c.3134A>C p.K1045T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60891043; called by muse, mutect2, varscan2
- SRRM4 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.997); catalogued as rs550204730, COSV57423567; called by muse, mutect2, varscan2
- SSR3 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54021421; called by muse, mutect2, varscan2
- STIM2 | c.2095T>G p.S699A | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.369); catalogued as COSV52842552; called by muse, mutect2, varscan2
- TAS1R1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs767318686, COSV59840478; called by muse, mutect2, varscan2
- TET3 | c.2019G>C p.R673S | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV59882320; called by muse, mutect2
- TG | c.5225T>C p.V1742A | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV55090320; called by muse, mutect2, varscan2
- TLE1 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 52/141 reads (37%) | catalogued as rs1440453806, COSV64722911; called by muse, mutect2, varscan2
- TRGC1 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs770761246; called by muse, mutect2, varscan2
- UBA1 | c.2612A>G p.E871G | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV60114925; called by muse, mutect2, varscan2
- USP1 | c.1333A>G p.S445G | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.793); catalogued as COSV60575221; called by muse, mutect2
- VEZT | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54135576; called by muse, mutect2, varscan2
- YIPF3 | c.735C>G p.F245L | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV58306717; called by muse, mutect2, varscan2
- ZAR1L | c.918C>G p.D306E | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.795); catalogued as COSV61526269; called by muse, mutect2
- ZCCHC2 | c.1454T>G p.L485* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as COSV54040362; called by muse, mutect2, varscan2
- ZMAT4 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 25/116 reads (22%) | catalogued as COSV52710836; called by muse, mutect2, varscan2
- ZNF141 | c.549T>A p.F183L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53659811, COSV53661037; called by muse, mutect2, varscan2
- ZNF430 | c.1693A>G p.R565G | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV55112030; called by muse, mutect2, varscan2
- ZNF441 | c.1592A>G p.Y531C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs781511935, COSV63540653; called by muse, mutect2, varscan2
- ZNF536 | c.2363G>A p.G788D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62826205; called by muse, mutect2, varscan2
- CUL9 | c.5348_5351del p.N1783Rfs*7 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | called by mutect2, varscan2
- GRIA1 | c.1650_1658del p.S551_V553del | In Frame Del (DEL) | VAF 53/376 reads (14%) | called by mutect2, pindel, varscan2
- ITPR1 | c.874_878del p.C292Gfs*28 | Frame Shift Del (DEL) | VAF 37/144 reads (26%) | called by mutect2, pindel, varscan2
- MUC19 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RANBP10 | c.338del p.G113Efs*8 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- RMDN1 | c.636dup p.I213Yfs*18 | Frame Shift Ins (INS) | VAF 28/108 reads (26%) | called by mutect2, pindel, varscan2
- SGO2 | c.254_256del p.E85del | In Frame Del (DEL) | VAF 12/64 reads (19%) | called by pindel, varscan2
- UGT2B4 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 12/88 reads (14%) | called by pindel, varscan2
- VAV3 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ARL5A | c.132A>G p.T44= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as rs776861293, COSV54471222; called by muse, mutect2, varscan2
- ARR3 | c.1116C>T p.G372= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs1569223613, COSV52105018; called by muse, mutect2, varscan2
- BMP1 | c.1344G>A p.S448= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs199778498, COSV60482667; called by muse, mutect2, varscan2
- CACNG2 | c.639C>T p.R213= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs762691427, COSV55635202; called by muse, mutect2, varscan2
- CDK5RAP2 | c.600A>G p.S200= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV62577224; called by muse, mutect2, varscan2
- COL6A3 | c.8694T>C p.T2898= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs537384335, COSV55104137; called by muse, mutect2, varscan2
- CTCFL | c.1989G>A p.K663= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV54777957; called by muse, mutect2, varscan2
- DECR1 | c.414T>C p.P138= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV55170196; called by muse, mutect2, varscan2
- DNAH5 | c.6699T>C p.A2233= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV54245989; called by muse, mutect2, varscan2
- DRC1 | c.1833G>A p.E611= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs770534903, COSV55515272; called by muse, mutect2, varscan2
- FAT2 | c.219C>A p.I73= | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as rs1219424693, COSV55827291; called by muse, mutect2, varscan2
- GLI3 | c.105C>T p.A35= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV67893689; called by muse, mutect2, varscan2
- ITIH4 | c.171G>A p.V57= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV56577589; called by muse, mutect2, varscan2
- KIF13B | c.4374G>C p.V1458= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV68094628; called by muse, mutect2, varscan2
- LBP | c.531G>A p.L177= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs753612358, COSV54142861; called by muse, mutect2, varscan2
- PAX4 | c.207A>G p.P69= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV58390614; called by muse, mutect2
- RGS22 | c.3228T>C p.I1076= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV62666255; called by muse, mutect2, varscan2
- RIMS2 | c.2047C>A p.R683= (on ENST00000666250 / NM_001348490.2; = p.R491= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV51660737, COSV51713622; called by muse, mutect2, varscan2
- SLITRK2 | c.42C>A p.A14= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as COSV59427981; called by muse, mutect2, varscan2
- TRAPPC8 | c.3978A>G p.Q1326= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV51976234; called by muse, mutect2, varscan2
- ZIC1 | c.738C>T p.F246= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as COSV51552170, COSV51556900; called by muse, mutect2, varscan2
- ZNF175 | c.900T>A p.I300= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV51797825; called by muse, mutect2, varscan2
- C9orf85 | c.102+6692G>A | Intron (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- FUT9 | c.*4149_*4160del | 3'UTR (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- GULP1 | c.-172+4426C>T | Intron (SNP) | VAF 42/104 reads (40%) | catalogued as COSV63072440; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.291+11172A>T | Intron (SNP) | VAF 29/108 reads (27%) | catalogued as COSV61854893; called by muse, mutect2, varscan2
- LRRC10B | c.*334G>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100958531; called by muse, mutect2
- MARCHF1 | c.-322-86016C>T | Intron (SNP) | VAF 33/101 reads (33%) | catalogued as rs1233255479, COSV72277403; called by muse, mutect2, varscan2
- MIR600 | chr9:123114137 G>A | 5'Flank (SNP) | VAF 19/71 reads (27%) | catalogued as rs1325811893; called by muse, mutect2, varscan2
- OPRM1 | chr6:154039207 A>T | 5'Flank (SNP) | VAF 10/142 reads (7%) | catalogued as COSV57683254; called by muse, mutect2
- ST7 | c.151+3023A>G | Intron (SNP) | VAF 20/62 reads (32%) | catalogued as COSV55390995; called by muse, mutect2, varscan2
- TRPM1 | c.724+978G>T | Intron (SNP) | VAF 22/59 reads (37%) | catalogued as COSV56640270; called by muse, mutect2, varscan2
- ZNF99 | c.*852G>C | 3'UTR (SNP) | VAF 16/42 reads (38%) | catalogued as COSV101233878, COSV101234006; called by muse, mutect2, varscan2
